Surgical pathology report (de-identified scan), TCGA case TCGA-30-1718, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1718-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED]

Report Status: Final

Type: Surgical Pathology

Pathology Report

OMENTUM BIOPSY

Accessioned On: [REDACTED]

DIAGNOSIS:

SPECIMEN LABELED "RECTUS MUSCLE":

Gross exam of the muscle only. The specimen was sent to [REDACTED] lab for special studies.

SPECIMEN LABELED "OMENTAL TUMOR":

PAPILLARY SEROUS CARCINOMA, poorly differentiated.

SPECIMEN LABELED "TUMOR FROM EDGE OF GALLBLADDER":

PAPILLARY SEROUS CARCINOMA, poorly differentiated.

TCGA-30-1718

SPECIMEN LABELED "TUMOR FROM TRANSVERSE COLON":

PAPILLARY SEROUS CARCINOMA, poorly differentiated.

SPECIMEN LABELED "RIGHT OVARY AND TUBE":

Ovary:

PAPILLARY SEROUS CARCINOMA poorly differentiated, involving the surface of the ovary.

Fallopian tube:

PAPILLARY SEROUS CARCINOMA involving the tubal mucosa.
Peritubal adhesions.

SPECIMEN LABELED "LEFT OVARY AND TUBE":

Ovary:

PAPILLARY SEROUS CARCINOMA, poorly differentiated, involving the surface of the ovary.

Fallopian tube:

PAPILLARY SEROUS CARCINOMA, poorly differentiated, involving mesosalpinx.

SPECIMEN LABELED "UTERUS AND CERVIX" (107 gm uterus):

Cervix:

Squamous metaplasia and mucous cyst.

Endometrium:

Proliferative endometrium.

Myometrium:

No significant pathologic change.

Serosa:

PAPILLARY SEROUS CARCINOMA.

SPECIMEN LABELED "TUMOR FROM BLADDER":

PAPILLARY SEROUS CARCINOMA.

Comment: The presentation is characteristic of PRIMARY PERITONEAL SEROUS CARCINOMA.

CLINICAL DATA:

History: [REDACTED] ascites, positive adenocarcinoma increase CA125.

Operation: Exploratory laparotomy, TAH BSO

Clinical Diagnosis: Ascites

TISSUE SUBMITTED: 1. Rectus muscle (FS)

2. Omental tumor (FS)

3. Tumor from edge of gallbladder

4. Tumor from transverse colon

5. Right tube & ovary

6. Left tube & ovary

7. Uterus & cervix

[page 2 of 3]
8. Tumor from bladder

O.R. CONSULTATION:

SPECIMEN LABELED "#2 OMENTAL TUMOR" (FSA):

Papillary serous carcinoma.

GROSS DESCRIPTION:

The specimen is received fresh in eight parts, each labeled with the patient's name and unit number.

Part one, "rectus muscle", consists of a fragment of red/tan soft tissue (1.8 x 1.2 x 1.0 cm). The specimen is entirely submitted for special studies to [REDACTED].

Part two, "omental tumor", consists of a fragment of adipose tissue which is extensive involved by confluent white/tan firm tissue. Representative sections are submitted as FSA and special studies and tissue bank. Omental tumor is oriented. Representative sections are submitted.

Micro sections:

Micro 1: frozen section A remnant.

Micro 2-5: representative sections of omentum tumor, 4 frags, [REDACTED]

TCGA-30-1718

Part three, "tumor from edge of gallbladder", consists of a fragment of white/yellow/tan soft tissue (6.0 x 4.0 x 2.0 cm). The soft tissue is unoriented and representative sections of this soft tissue are submitted.

Micro 6-7: tumor from edge of gallbladder, 3 frags, [REDACTED]

Part four, "tumor from transverse colon", consists of a fragment of white/yellow/tan soft tissue (8.0 x 8.0 x 1.2 cm). The specimen is unoriented and representative sections are submitted.

Micro 8-9: tumor from transverse colon, 2 frags, [REDACTED]

Part five, "right tube & ovary", consists of an ovary (1.0 x 2.0 x 1.2 cm) and a fallopian tube (5.0 cm in length and 0.6 cm in diameter). The fallopian tube is patent and has fimbriated end. The gross exam of fallopian tube is unremarkable. The ovary has a smooth, white surface and is sectioned at approximately 3 mm intervals revealing white/yellow/tan resection surface with no hemorrhage or necrotic areas or nodules.

Micro 10: representative sections of the ovary, 2 frags, [REDACTED]

Micro 11: representative sections of right fallopian tube, 3 frags, [REDACTED]

Part six, "left tube & ovary", consists of an ovary (3.8 x 2.2 x 1.8 cm) and a fallopian tube (4.5 cm in length and 0.6 cm in diameter). The fallopian tube is patent and has a fimbriated end. The gross exam of fallopian tube is unremarkable. The left ovary has a smooth white surface and is sectioned at approximately 0.3 cm interval revealing white/tan yellow resection surface with multiple lobulated cystic lesions which are filled with clear fluid.

Micro 12-13: left ovary, 3 frags, [REDACTED]

Micro 14: left fallopian tube, 3 frags, [REDACTED]

Part seven, "uterus & cervix", consists of a 107 gm uterus (11 x 7.5 x 3.0 cm). The exocervix (4 x 3.5 cm) is covered by smooth glistening white mucosa. The external os is slit and measures 2.0 cm. The endocervical canal (2.5 cm) has a tan herringbone mucosa. The endometrial cavity (2.5 cm from cornu to cornu, 3.7 cm in length) has a tan/pink endometrium (0.4 cm in average thickness). The myometrium measures 2.2 cm in maximum thickness. The serosa is smooth and glistening.

Micro 15: anterior cervix, 1 frag, [REDACTED]

Micro 16-17: posterior cervix, 2 frags, [REDACTED]

Micro 18: anterior lower uterine segment, 1 frag, [REDACTED]

Micro 19: posterior lower uterine segment, 1 frag, [REDACTED]

Micro 20: anterior endometrium, 1 frag, [REDACTED]

Micro 21: posterior endometrium, 1 frag, [REDACTED]

[page 3 of 3]
Part eight, "tumor from bladder", consists of an unoriented red/pink/white soft tissue (8 x 5 x 0.9 cm). Both sides of the soft tissue of irregular shaped and with multiple possible adhesions. Representative sections of the mass are submitted.

Micro 22-24: representative sections of tumor from bladder, 6 frags, [REDACTED]

Reports to: [REDACTED]

SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: UTERUS WITH OR WITHOUT TUBES & OVARIES, NEOPLASTIC

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

TCGA-30-1718

Source: NCI Genomic Data Commons file eb496b88-43bf-4285-8bc9-9855896daf05 (TCGA-30-1718.078DA76A-B9F5-40D0-9A57-04C306ADE36A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).